Gene-level copy-number profile of tumor specimen TCGA-LN-A49P-01A from TCGA case TCGA-LN-A49P, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.7 years (26,189 days).
Specimen TCGA-LN-A49P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.02fcfd20-095f-4947-862f-fd128292d316.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b076214-c3cb-4f05-ab9c-2d7afb77452d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 5,368; copy number 2: 35,039; copy number 3: 10,782; copy number 4: 4,588; copy number 5: 1,932; copy number 6: 1,734; copy number 7: 71; copy number 8: 26; copy number 9: 92; copy number 10: 37; copy number 13: 34; copy number 14: 10; copy number 17: 3; copy number 24: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49P-01A-11D-A246-01): tumor purity 0.41, ploidy 2.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:67,225,464–67,306,359, 2 genes: MIR4272, AC114401.1.
- chr9:21,304,326–27,610,745, 85 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,945 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:113,696,831–121,580,524, 184 genes, copy number 5–6 (broad region; genes not listed).
- chr3:197,889,077–198,222,513, 13 genes, copy number 6: IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:43,972,921–49,062,081, 58 genes, copy number 9: AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr4:157,568,731–157,824,256, 1 gene, copy number 5 (within-gene range 2–5): AC093817.2.
- chr4:157,768,013–162,164,004, 44 genes, copy number 5–7: Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AC098679.4, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233, AC093853.1, LINC02477, RPS14P7, AC104793.1, FSTL5, AC023136.1.
- chr6:28,503,296–29,681,155, 68 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr6:32,254,640–32,981,505, 35 genes, copy number 5 (within-gene range 3–5): TSBP1-AS1, TSBP1, HNRNPA1P2, RNU6-603P, BTNL2, HLA-DRA, HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1, AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z, HLA-DMB, AL645941.2, HLA-DMA, BRD2, AL645941.1, AL645941.3.
- chr7:63,011,463–134,998,153, 1,347 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:41,828,165–46,974,617, 78 genes, copy number 5 (broad region; genes not listed).
- chr8:58,805,412–59,119,147, 1 gene, copy number 6 (within-gene range 4–6): TOX.
- chr8:58,991,720–145,066,685, 1,333 genes, copy number 6 (broad region; genes not listed).
- chr9:27,829,276–27,944,497, 2 genes, copy number 17: AL360014.1, AL353746.1.
- chr9:28,148,211–28,149,236, 1 gene, copy number 17: AL451124.1.
- chr10:34,663,859–36,442,392, 34 genes, copy number 10: RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2.
- chr11:32,583,798–37,726,456, 88 genes, copy number 5–24 (broad region; genes not listed).
- chr15:91,303,756–98,420,998, 124 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr15:100,344,047–101,933,350, 57 genes, copy number 6: SPATA41, CERS3-AS1, CERS3, AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr19:29,001,670–37,614,179, 303 genes, copy number 5–13 (broad region; genes not listed).
- chr19:44,613,563–46,077,118, 86 genes, copy number 5 (broad region; genes not listed).
- chr19:46,111,079–46,124,688, 2 genes, copy number 5: AC007785.2, IGFL3.
- chr19:47,819,779–48,457,022, 26 genes, copy number 9 (within-gene range 2–9): CRX, TPRX2P, LINC01595, SULT2A1, BSPH1, ELSPBP1, CABP5, PLA2G4C, PLA2G4C-AS1, LIG1, AC011466.3, AC011466.2, ZSWIM9, CARD8, AC011466.4, AC011466.1, CARD8-AS1, ZNF114-AS1, ZNF114, CCDC114, EMP3, TMEM143, SYNGR4, KDELR1, GRIN2D, GRWD1.
- chr20:30,484,925–32,355,734, 60 genes, copy number 6: 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1.

Autosomal genes at a single copy (total copy number 1): 4,554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
